Gene-level copy-number profile of tumor specimen TCGA-19-A6J5-01A from TCGA case TCGA-19-A6J5, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 41.0 years (14,970 days).
Specimen TCGA-19-A6J5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.cedbe7d9-e27d-4550-9d8f-69b6d0a6e6b4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-19-A6J5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f31026c2-b286-4cb9-8e18-461f84e824c8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 51; copy number 1: 513; copy number 2: 6,459; copy number 3: 1,991; copy number 4: 44,573; copy number 5: 710; copy number 6: 4,486; copy number 7: 69; copy number 8: 553; copy number 10: 33; copy number 11: 143; copy number 12: 69; copy number 13: 47; copy number 17: 30; copy number 18: 32; copy number 19: 31; copy number 20: 11; copy number 21: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-19-A6J5-01A-21D-A33S-01): tumor purity 0.96, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 51 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,695,176–22,128,103, 16 genes: KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr10:87,607,985–87,747,705, 4 genes (within-gene range 0–2): AL138767.3, AL138767.1, RPS26P38, PAPSS2.
- chr10:88,048,135–88,049,823, 1 gene: MED6P1.
- chr19:42,086,110–42,670,816, 30 genes: POU2F2, AC010247.1, MIR4323, AC010247.2, DEDD2, AC006486.3, ZNF526, GSK3A, AC006486.1, AC006486.2, ERF, CIC, PAFAH1B3, PRR19, TMEM145, MEGF8, MIR8077, CNFN, LIPE-AS1, LIPE, AC011497.1, CXCL17, RNU4-60P, AC011497.2, CEACAM1, CEACAMP2, CEACAM8, CEACAMP1, CEACAMP5, RPS10P28.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 405 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:7,533,595–7,647,873, 10 genes, copy number 12: AC008878.2, PNPLA6, CAMSAP3, MIR6792, XAB2, PET100, AC008763.2, PCP2, AC008763.1, STXBP2.
- chr19:9,412,461–10,010,504, 30 genes, copy number 10 (within-gene range 4–10): ZNF266, AC011451.4, ZNF560, AC008567.2, AC008567.3, AC008567.1, ZNF426, ZNF426-DT, ZNF121, ZNF561, ZNF561-AS1, ZNF562, RPS4XP22, ZNF812P, AC008759.3, AC008759.1, AC008759.2, ZNF846, AC008752.3, UBE2L4, AC008752.1, FBXL12, SNORA70, RPL10P15, UBL5, AC008752.2, PIN1, OLFM2, COL5A3, AC008742.1.
- chr19:11,721,265–13,633,025, 123 genes, copy number 11 (within-gene range 4–11) (broad region; genes not listed).
- chr19:17,747,718–17,821,574, 3 genes, copy number 10: FCHO1, B3GNT3, INSL3.
- chr19:29,448,038–31,349,436, 30 genes, copy number 17 (within-gene range 4–17): AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791.
- chr19:51,350,373–52,030,240, 54 genes, copy number 13–18 (within-gene range 4–18): AC008750.7, AC008750.4, CLDND2, NKG7, LIM2, C19orf84, AC008750.6, NIFKP6, SIGLEC10, AC008750.1, SIGLEC10-AS1, AC008750.5, AC020914.5, SIGLEC8, AC020914.3, CEACAM18, SIGLEC12, AC020914.2, SIGLEC27P, SIGLEC6, AC020914.1, AC020914.4, SIGLEC29P, ZNF175, AC018755.3, AC018755.1, SIGLEC5, AC018755.2, RPL9P33, AC018755.4, SIGLEC14, RPL7P51, SPACA6P-AS, SPACA6, MIR99B, MIRLET7E, MIR125A, HAS1, FPR1, FPR2, AC018755.5, FPR3, ZNF577, AC006272.1, AC006272.2, AC074141.1, ZNF649-AS1, ZNF649, AC011460.1, ZNF613, ZNF350-AS1, ZNF350, ZNF615, ZNF614.
- chr21:16,754,519–19,303,739, 36 genes, copy number 13–20: AF130359.1, AF212831.1, NEK4P1, AP000457.1, RNU6-113P, LINC01549, RPL39P40, RN7SL163P, CXADR, BTF3L4P1, Y_RNA, Y_RNA, BTG3, BTG3-AS1, AP000432.1, AP000432.2, C21orf91-OT1, C21orf91, AL109761.1, CHODL-AS1, RPL37P3, CHODL, AF130417.1, TMPRSS15, AL109763.1, MIR548XHG, AF240627.1, MIR548X, PPIAP22, AL157359.3, AL157359.2, AL157359.1, AP000431.2, AP000431.1, SLC6A6P1, AP000855.1.
- chr21:22,436,290–26,573,286, 60 genes, copy number 11–21: MAPK6P2, AP000959.1, AP000949.1, AP001116.1, MIR6130, ZNF299P, MSANTD2P1, AP001255.1, RNU2-55P, D21S2088E, EEF1A1P1, TUBAP1, Y_RNA, AP000459.1, AP000961.1, AP000474.2, AP000474.1, AP000477.2, AP000477.3, AP000477.1, AP000470.1, LINC01689, LINC01684, LINC01692, AP000402.1, AP000146.1, AP001342.1, AP000235.1, AP000233.2, RN7SKP236, AP000233.1, AP001341.1, RNA5SP489, RPL13AP7, AP001340.1, LINC00158, AP000221.1, MIR155HG, MIR155, AP000223.1, MRPL39, JAM2, RNGTTP1, AP000224.1, FDX1P2, ATP5PF, GABPA, LLPHP2, APP, AP001442.1, RNU6-123P, AP001439.1, AP000229.1, RNU6-926P, AP001595.2, AP001595.1, AP001596.1, CYYR1-AS1, AP001596.2, CYYR1.
- chr21:44,497,893–44,711,572, 1 gene, copy number 12 (within-gene range 4–12): TSPEAR.
- chr21:44,573,724–45,974,953, 58 genes, copy number 12: KRTAP10-4, KRTAP10-5, KRTAP10-6, KRTAP10-7, KRTAP10-8, KRTAP10-9, KRTAP10-10, KRTAP10-11, KRTAP12-4, KRTAP12-3, KRTAP12-2, IMMTP1, KRTAP12-1, KRTAP12-6P, KRTAP10-12, KRTAP10-13P, UBE2G2, LINC01424, SUMO3, PTTG1IP, ITGB2, ITGB2-AS1, AL844908.2, LINC01547, AL844908.1, FAM207A, AP001505.1, LINC00163, LINC00165, PICSAR, SSR4P1, ADARB1, AL133499.1, LINC00334, POFUT2, LINC00205, BX322557.2, LINC00315, BX322557.1, LINC00316, MTCO1P3, BX322559.1, BX322562.1, COL18A1, COL18A1-AS2, COL18A1-AS1, MIR6815, SLC19A1, LINC01694, AL133493.1, AL133493.2, PCBP3, AL133492.1, PCBP3-AS1, AJ011931.2, AJ011931.1, AJ239328.1, AJ011932.1.

Autosomal genes at a single copy (total copy number 1): 513. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
